Somatic mutation profile of tumor specimen MMRF_2428_1_BM_CD138pos (aliquot MMRF_2428_1_BM_CD138pos_T1_KHS5U_L11231) from MMRF case MMRF_2428, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.2 years (19,783 days).
Specimen MMRF_2428_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d322d1d3-f622-496e-82d7-ba67fad371a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2428_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2428_1_PB_Whole_C2_KHS5U_L11232; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b06bae1b-50b9-463b-911d-f5ed377afe43

The open-access MAF lists 88 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 28, Silent 12, Intron 6, 5'UTR 3, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.774); catalogued as rs121913528, COSV55499283, COSV55796966; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AFTPH | c.1302T>G p.D434E | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV53217028; called by muse, mutect2
- AP002512.3 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV54408487, COSV54409662; called by muse, mutect2, varscan2
- C10orf90 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.682); catalogued as rs1455030805; called by muse, mutect2, varscan2
- COL6A3 | c.6021G>T p.R2007S | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV55085585; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1187952369, COSV62567667; called by muse, mutect2, varscan2
- FREM1 | c.6309G>A p.W2103* | Nonsense Mutation (SNP) | VAF 32/126 reads (25%) | catalogued as COSV66522954; called by muse, mutect2, varscan2
- IGHV2-70 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 88/150 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs568191048; called by muse, varscan2
- IGHV2-70 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 50/192 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs568002484; called by muse, varscan2
- IGHV2-70 | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs546731210; called by muse, varscan2
- IGHV2-70D | c.341A>C p.Y114S | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1414572352; called by muse, varscan2
- IGHV2-70D | c.274A>G p.K92E | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as rs1451105528; called by muse, varscan2
- IGHV3-30 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as rs564169233; called by muse, mutect2, varscan2
- KMT2D | c.10493C>T p.A3498V | Missense Mutation (SNP) | VAF 159/372 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs1240983082; called by muse, mutect2, varscan2
- KRAS | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs104886029, COSV55568979, COSV55604554, COSV55904854; ClinVar: not provided; called by muse, mutect2, varscan2
- OLFM1 | c.878G>A p.R293H (on ENST00000371793 / NM_001282611.2; = p.R275H on NM_014279.5) | Missense Mutation (SNP) | VAF 80/754 reads (11%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.98); catalogued as rs1259537651, COSV53279856; called by muse, mutect2, varscan2
- OR9G1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs373762637; called by muse, mutect2, varscan2
- PHRF1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752351035; called by muse, mutect2, varscan2
- ZBTB7A | c.1365C>G p.N455K | Missense Mutation (SNP) | VAF 181/352 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100475966; called by muse, mutect2, varscan2
- ZNF493 | c.1806A>T p.K602N | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.055); catalogued as COSV62749758; called by muse, mutect2, varscan2
- ADAMTS6 | c.2458T>A p.L820M | Missense Mutation (SNP) | VAF 83/339 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C11orf42 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DKKL1 | c.648del p.T217Pfs*56 | Frame Shift Del (DEL) | VAF 98/373 reads (26%) | called by mutect2, pindel, varscan2
- ECPAS | c.1373C>G p.S458C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FREM1 | c.6310G>C p.D2104H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- HGS | c.1503G>C p.E501D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSP90AA1 | c.701A>C p.E234A | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- LRCH3 | c.680G>T p.C227F | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- NTS | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NTS | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 66/258 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR9G4 | c.768_771del p.F257Cfs*11 | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | called by mutect2, pindel, varscan2
- POLR3A | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF111 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF111 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEM1 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRAF3 | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 110/160 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAPPC11 | c.1132A>T p.N378Y | Missense Mutation (SNP) | VAF 56/247 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- ZRANB1 | c.899T>A p.V300E | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ABL1 | c.2475C>T p.A825= | Silent (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- AMPD3 | c.468C>T p.A156= (on ENST00000396553 / NM_001025389.2; = p.A165= on NM_000480.3) | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2, varscan2
- BIN1 | c.1308C>T p.S436= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs760959487; called by muse, mutect2, varscan2
- CNTNAP4 | c.1566C>T p.S522= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs755624525, COSV56680566; called by muse, mutect2
- FAM189A2 | c.1107G>A p.E369= | Silent (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- GIPR | c.69G>A p.A23= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1447518483; called by muse, mutect2, varscan2
- MTHFR | c.1035T>C p.R345= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- MYO9B | c.648C>T p.F216= | Silent (SNP) | VAF 85/368 reads (23%) | catalogued as rs1181898052; called by muse, mutect2, varscan2
- NUMA1 | c.2346T>C p.T782= | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- PDE2A | c.315G>A p.G105= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as COSV57812828; called by muse, mutect2, varscan2
- SPAG9 | c.2292T>G p.T764= (on ENST00000262013 / NM_001130528.3; = p.T750= on NM_003971.6) | Silent (SNP) | VAF 62/174 reads (36%) | called by muse, mutect2, varscan2
- TBC1D21 | c.906C>T p.N302= | Silent (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- ACTL10 | c.*35G>A | 3'UTR (SNP) | VAF 72/193 reads (37%) | called by muse, mutect2, varscan2
- CCDC113 | c.*3187G>A | 3'UTR (SNP) | VAF 56/153 reads (37%) | catalogued as rs941907483; called by muse, mutect2, varscan2
- CD200R1 | c.*1822A>C | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- CDKL3 | c.1720-973T>C | Intron (SNP) | VAF 159/751 reads (21%) | called by muse, mutect2, varscan2
- CTRC | c.*203C>T | 3'UTR (SNP) | VAF 18/33 reads (55%) | catalogued as rs1368680967, COSV65621497; called by muse, mutect2, varscan2
- CYP2F1 | c.*243G>C | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, varscan2
- DPPA4 | c.*1495G>T | 3'UTR (SNP) | VAF 60/100 reads (60%) | called by muse, mutect2, varscan2
- DRD2 | c.*411G>A | 3'UTR (SNP) | VAF 60/193 reads (31%) | called by muse, mutect2, varscan2
- EFCAB1 | c.*776C>A | 3'UTR (SNP) | VAF 41/119 reads (34%) | catalogued as rs1286354779; called by muse, mutect2, varscan2
- EMB | c.*1052T>C | 3'UTR (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- FAM53B | c.*402G>A | 3'UTR (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- FOXA1 | c.*761C>A | 3'UTR (SNP) | VAF 12/41 reads (29%) | catalogued as rs946276319; called by muse, mutect2, varscan2
- GALNT17 | c.*880G>A | 3'UTR (SNP) | VAF 61/204 reads (30%) | called by muse, mutect2, varscan2
- GFI1B | c.*127G>C | 3'UTR (SNP) | VAF 19/70 reads (27%) | called by muse, mutect2, varscan2
- GLRB | c.*899G>C | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- GNB5 | c.864-16T>G | Intron (SNP) | VAF 48/219 reads (22%) | called by muse, mutect2, varscan2
- GOLT1B | c.*2154A>G | 3'UTR (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- HEATR9 | c.511-81C>A | Intron (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- HOXD13 | c.*119G>T | 3'UTR (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- HTRA3 | c.1051+1719T>C | Intron (SNP) | VAF 97/170 reads (57%) | catalogued as rs1172780078; called by muse, mutect2, varscan2
- IGLON5 | c.*1406C>A | 3'UTR (SNP) | VAF 29/724 reads (4%) | called by muse, mutect2
- INSRR | c.-375C>T | 5'UTR (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- LGI2 | c.*4459_*4462del | 3'UTR (DEL) | VAF 53/99 reads (54%) | called by mutect2, pindel, varscan2
- MMP16 | c.*9071T>A | 3'UTR (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2, varscan2
- NADSYN1 | c.1047+48T>A | Intron (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- PRR5L | c.*2462C>A | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- PSTPIP2 | c.*1269C>T | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- PTEN | c.*1380G>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- SAMD8 | c.-11C>T | 5'UTR (SNP) | VAF 74/187 reads (40%) | catalogued as rs780095818, COSV101014035; called by muse, mutect2, varscan2
- SENP6 | c.*1868A>G | 3'UTR (SNP) | VAF 45/135 reads (33%) | called by muse, mutect2, varscan2
- SPRY3 | c.*4851T>G | 3'UTR (SNP) | VAF 125/301 reads (42%) | called by muse, mutect2, varscan2
- SPTLC3 | c.*758T>C | 3'UTR (SNP) | VAF 23/84 reads (27%) | catalogued as rs1444643957; called by muse, mutect2
- STC2 | c.*2233_*2235del | 3'UTR (DEL) | VAF 27/176 reads (15%) | called by mutect2, pindel, varscan2
- TMEM8B | c.*57G>T | 3'UTR (SNP) | VAF 80/280 reads (29%) | catalogued as COSV65078103; called by muse, mutect2, varscan2
- TMPRSS11D | c.475+33C>T | Intron (SNP) | VAF 15/46 reads (33%) | catalogued as rs1336590852; called by muse, mutect2, varscan2
- YAP1 | c.-316A>G | 5'UTR (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2
- YOD1 | c.*4253G>A | 3'UTR (SNP) | VAF 28/680 reads (4%) | called by muse, mutect2
